Gene-level copy-number profile of tumor specimen TCGA-IG-A4QS-01A from TCGA case TCGA-IG-A4QS, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Thoracic esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.9 years (26,273 days).
Specimen TCGA-IG-A4QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.2e2fe4e3-15b1-41c6-9611-58b5b15fdc4b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A4QS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/265061fa-7957-4f27-bbce-d009f2da5792

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 746; copy number 2: 20,931; copy number 3: 25,269; copy number 4: 5,224; copy number 5: 5,934; copy number 6: 626; copy number 7: 318; copy number 8: 661; copy number 10: 11; copy number 13: 1; copy number 15: 58; copy number 19: 2; copy number 47: 14; copy number 60: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A4QS-01A-11D-A25X-01): tumor purity 0.61, ploidy 5.62, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr16:78,793,584–78,826,006, 2 genes: AC009141.1, RPS3P7.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,085 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,921,951–2,391,707, 14 genes, copy number 47 (within-gene range 5–47): CFAP74, AL391845.2, GABRD, AL391845.1, PRKCZ, AL590822.2, PRKCZ-AS1, FAAP20, AL590822.1, SKI, AL590822.3, MORN1, AL589739.1, AL513477.1.
- chr1:12,230,030–15,526,534, 78 genes, copy number 8–15 (within-gene range 5–23) (broad region; genes not listed).
- chr8:84,182,787–145,066,685, 967 genes, copy number 7–19 (within-gene range 5–19) (broad region; genes not listed).
- chr10:42,782,795–43,130,351, 6 genes, copy number 7 (within-gene range 3–7): BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100, RET.
- chr12:24,949,163–25,648,579, 20 genes, copy number 60 (within-gene range 2–60): AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1.

Autosomal genes at a single copy (total copy number 1): 746. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
